Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YY, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YY-01A (Primary Tumor).

Patient: [REDACTED]

Surgical Pathology: Final [REDACTED] Accr: [REDACTED]

Surg Path

CLINICAL HISTORY:

Right frontal brain tumor.

GROSS EXAMINATION:

A. "Brain tumor (AF1)", received fresh for frozen section. A 5 x 4.5 x 2.3 cm aggregate of multiple fragments of yellow and gray-tan tissue and blood clot is received. Portions of the specimen have been previously submitted as frozen section remnant is submitted in Block A1, and representative of the remainder of the tissue is submitted in Blocks A2-A6.

B. "Brain tumor (anterior)", received fresh and placed in formalin. A 4.5 x 3.3 x up to 1.8 cm fragment is received. Multiple representative submitted in Blocks B1-B5.

C. "Brain tumor", received fresh and placed in formalin. A 3.5 x 3 x 1.0 cm aggregate of multiple fragments of soft pink and white tissue is received. Representative retained in formalin and the remainder is submitted in Blocks C1-C3.

INTRA OPERATIVE CONSULTATION:

A. "Brain tumor": AF1- astrocytoma, probably low grade (Dr.

MICROSCOPIC EXAMINATION:

The specimen in container A labeled "brain tumor AF1", in container B labeled "brain tumor anterior" and in container C labeled "brain tumor" consists of tissue which is infiltrated or replaced by a population of neoplastic cells. The cells have round nuclei with stippled chromatin and perinuclear halos are noted in many regions. Focal calcification is seen and perineuronal satellitosis is also present. In some areas, endothelial cells are plump and foci of macrophages are present.

DIAGNOSIS:

A. "BRAIN TUMOR AF1":

WELL DIFFERENTIATED OLIGODENDROGLIOMA (WHO GRADE II).

B. "BRAIN TUMOR ANTERIOR":

WELL DIFFERENTIATED OLIGODENDROGLIOMA (WHO GRADE II).

C. "BRAIN TUMOR":

WELL DIFFERENTIATED OLIGODENDROGLIOMA (WHO GRADE II).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed [REDACTED]

ICD-O 3
Oligodendroglioma, grade II
9450/3
Site: Brain, supratentorial NOS
C71.0
path Brain NOS
C71.9
JFD 5/5/14

Printed by:

Source: NCI Genomic Data Commons file 69a63863-9a5b-444e-9c7a-2c71724f9894 (TCGA-E1-A7YY.EBCF38D8-E69D-4F12-B7F5-29578E560B44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).